TCGA case TCGA-13-0901 — Ovarian Serous Cystadenocarcinoma (TCGA-OV)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Cystic, Mucinous and Serous Neoplasms; Primary site: Ovary; Tissue source site: Memorial Sloan Kettering. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/27920e1e-b9ab-4587-970a-0cba7025becb

Demographics
Sex at birth: female; Race: asian; Ethnicity: not hispanic or latino; Age at index: 41 years; Vital status: Alive.

Diagnoses (2)
1. Serous cystadenocarcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8441/3; ICD-10 code: C56.9; Tissue or organ of origin: Ovary; Site of resection or biopsy: Ovary; Laterality: Bilateral; Classification of tumor: primary; Age at diagnosis: 42.0 years (15,333 days); Year of diagnosis: 2004; Method of diagnosis: Surgical Resection; FIGO stage: Stage IIIC; Tumor grade: G3; Prior treatment: No; Days to last follow up: 589 days (1.6 years).
   Pathology details: Residual tumor measurement: >20 mm.
   Treatment given: Treatment type: Targeted Molecular Therapy; Therapeutic agents: Cetuximab; Treatment intent type: Adjuvant; Days to treatment start: 44 days; Days to treatment end: 88 days; Treatment dose: 250 mg/m2.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cisplatin; Treatment intent type: Adjuvant; Days to treatment start: 44 days; Days to treatment end: 165 days; Number of cycles: 6; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Paclitaxel; Treatment intent type: Adjuvant; Days to treatment start: 44 days; Days to treatment end: 165 days; Number of cycles: 6; Treatment dose: 175 mg/m2; Route of administration: Intravenous.
   Recorded as not given: adjuvant Radiation Therapy, NOS.
2. Recurrence of diagnosis 1 (Serous cystadenocarcinoma, NOS). Age at diagnosis: 43.0 years (15,723 days); Days to diagnosis: 390 days (1.1 years); Prior treatment: Yes.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Recurrent Disease.
   Recorded as not given: Radiation Therapy, NOS, for recurrent disease.

Follow-up (3 entries)
- Day 390 (post initial treatment): Progression or recurrence: Yes; Days to recurrence: 390 days (1.1 years); Evidence of recurrence type: Convincing Image Source.
- Days to follow up: 589 days (1.6 years); Disease response: With Tumor.
- Karnofsky performance status: 80; Timepoint: Prior to Adjuvant Therapy.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-13-0901-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Longest dimension: 1.3; Intermediate dimension: 1; Shortest dimension: 0.4.
- Sample TCGA-13-0901-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Longest dimension: 1.3; Intermediate dimension: 1.3; Shortest dimension: 0.4.
  Slide TCGA-13-0901-01B-01-TS1: Section location: Top; Percent tumor cells: 89; Percent tumor nuclei: 90; Percent normal cells: 0; Percent necrosis: 1; Percent stromal cells: 10.
  Slide TCGA-13-0901-01B-01-BS1: Section location: Bottom; Percent tumor cells: 89; Percent tumor nuclei: 90; Percent normal cells: 0; Percent necrosis: 1; Percent stromal cells: 10.
- Sample TCGA-13-0901-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Histologic diagnosis: Serous Cystadenocarcinoma; Tumor status: With tumor; History neoadjuvant treatment: No; Performance status timing: Pre-Adjuvant Therapy; Method initial path diagnosis: Tumor resection.
- Drug treatment 2: Pharmaceutical therapy drug name: Paciltaxel.
- Drug treatment 2, Route of administrations: Route of administration: IV.
- Follow-up form: Treatment outcome first course: Complete Remission/Response; Tumor status: With tumor; Performance status timing: Pre-Adjuvant Therapy.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 589 days; disease-specific survival: no event (censored), 589 days; disease-free interval: event (new tumor event after initially disease-free), 390 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 390 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; sample TCGA-13-0901-01): tumor purity 0.78, ploidy 3.32, whole-genome doublings 1 (call status: legacy_call).
